Gene-level copy-number profile of tumor specimen HTMCP-03-06-02061-01A from CGCI case HTMCP-03-06-02061, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0db9df2b-cbc6-4c18-af0a-f14c9a84f558.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02061-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/773fe887-aa49-4e89-9c52-9813f97d76a4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 14; copy number 2: 13,114; copy number 3: 31,139; copy number 4: 11,600; copy number 5: 1,671; copy number 6: 770; copy number 7: 76.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,415,352–70,500,903, 4 genes: GTF2H2B, AC146944.2, NAIPP1, AC146944.1.
- chr6:32,517,353–32,589,848, 4 genes: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 76 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,007,512–22,513,998, 75 genes, copy number 7 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
